Somatic mutation profile of tumor specimen MP2PRT-PAVAMH-TMP1-A (aliquot MP2PRT-PAVAMH-TMP1-A-1-0-D-A820-36) from MP2PRT case MP2PRT-PAVAMH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.9 years (1,077 days).
Specimen MP2PRT-PAVAMH-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b40087e-8b80-436e-bc01-8cc95c97ffb8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVAMH-NM1-B (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVAMH-NM1-B-1-0-D-A820-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/789bba0a-d613-4da8-a6c3-f0f89bb90e75

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NES | c.2534C>G p.T845S | Missense Mutation (SNP) | VAF 159/437 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs1308873078; called by muse, mutect2, varscan2
- ZNF18 | c.601C>T p.R201* | Nonsense Mutation (SNP) | VAF 116/271 reads (43%) | catalogued as rs1307615761; called by muse, mutect2, varscan2
- BOLL | c.686G>A p.C229Y | Missense Mutation (SNP) | VAF 102/233 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- WWC1 | c.2183A>G p.E728G | Missense Mutation (SNP) | VAF 33/517 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF263 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 257/633 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.097); called by muse, mutect2, varscan2
